Somatic mutation profile of tumor specimen TARGET-30-PARHUX-01A (aliquot TARGET-30-PARHUX-01A-01D) from TARGET case TARGET-30-PARHUX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.9 years (698 days).
Specimen TARGET-30-PARHUX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f6e948e-c692-406a-9afa-c3a866dfb9f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARHUX-10A (Blood Derived Normal), aliquot TARGET-30-PARHUX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45b9bd87-b523-40c6-bab6-ba8301839d38

The open-access MAF lists 73 somatic variants for this specimen: 54 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 5, Splice Site 3, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV54384701; called by muse, mutect2, varscan2
- ACKR3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.6); catalogued as COSV56021647; called by muse, mutect2, varscan2
- ADGRG2 | c.1016C>A p.P339H (on ENST00000379869 / NM_001079858.3; = p.P336H on NM_005756.4) | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); catalogued as rs758337420, COSV61339075; called by muse, mutect2, varscan2
- ALS2CL | c.2532C>A p.I844= | Splice Region (SNP) | VAF 6/47 reads (13%) | catalogued as COSV59671300; called by mutect2, varscan2
- ARHGAP6 | c.2207G>T p.G736V (on ENST00000337414 / NM_013427.3; = p.G533V on NM_013423.3) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV57295733, COSV57305693; called by mutect2, varscan2
- ATP2A1 | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV63920982; called by muse, mutect2, varscan2
- ATP6V1E1 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53657998; called by muse, mutect2, varscan2
- C2CD3 | c.726C>A p.C242* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV58089334, COSV58092933; called by muse, mutect2, varscan2
- CA11 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV50033021; called by mutect2, varscan2
- CCL7 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52337005; called by muse, mutect2, varscan2
- CDCA2 | c.3008G>T p.G1003V | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV57945853; called by muse, mutect2, varscan2
- CFAP45 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs760907702, COSV63649009; called by muse, mutect2, varscan2
- COL20A1 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464377925, COSV58917042; called by muse, mutect2, varscan2
- COL6A6 | c.6549C>A p.N2183K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV62025005; called by muse, mutect2, varscan2
- COMMD2 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as rs1172204777, COSV71946476; called by mutect2, varscan2
- CPT1A | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55756015; called by muse, mutect2, varscan2
- CSH1 | c.457-1G>T p.X153_splice | Splice Site (SNP) | VAF 37/150 reads (25%) | catalogued as rs1567785710; called by mutect2, varscan2
- DEPDC5 | c.3753G>T p.Q1251H (on ENST00000400246; = p.Q1320H on NM_014662.5) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as COSV56697240; called by mutect2, varscan2
- ECEL1 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.259); catalogued as rs1280129715, COSV58812207; called by muse, mutect2, varscan2
- FRMPD1 | c.2885C>A p.A962D | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1412162831, COSV66700353; called by muse, mutect2, varscan2
- GLRB | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52416765; called by muse, mutect2, varscan2
- GRIA2 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.998); catalogued as COSV52389131, COSV52390112; called by muse, mutect2, varscan2
- HNF4A | c.738C>A p.G246= | Splice Region (SNP) | VAF 48/268 reads (18%) | catalogued as rs748537070, COSV100291792; called by muse, mutect2, varscan2
- HUWE1 | c.8530G>T p.A2844S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.093); catalogued as COSV53345030; called by muse, mutect2, varscan2
- IFNA6 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV66506384; called by muse, mutect2, varscan2
- IQCG | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as COSV54560382; called by muse, mutect2, varscan2
- KDELR3 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53247667; called by mutect2, varscan2
- KIF4A | c.3050C>A p.S1017Y | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV65543139; called by mutect2, varscan2
- LZTR1 | c.1439G>T p.R480M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53147410; called by muse, mutect2, varscan2
- MAPK3 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV53773433; called by mutect2, varscan2
- MIS18BP1 | c.2753G>T p.C918F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60370718; called by muse, mutect2, varscan2
- MSH6 | c.2178C>A p.F726L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV52279150; called by muse, mutect2, varscan2
- NTRK2 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52863596, COSV52876388; called by mutect2, varscan2
- OR4C6 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.049); catalogued as COSV58602677; called by muse, mutect2, varscan2
- OR6K2 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62743458; called by mutect2, varscan2
- PLCB4 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV53801382; called by mutect2, varscan2
- PRKAB1 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57555001; called by mutect2, varscan2
- PRKD1 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59568471; called by muse, mutect2, varscan2
- PRRC2C | c.7606G>T p.G2536* (on ENST00000367742; = p.G2534* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 72/181 reads (40%) | catalogued as COSV58905211; called by mutect2, varscan2
- PTPRM | c.2949G>T p.W983C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141406581, COSV59857751, COSV59858155; called by mutect2, varscan2
- RASGRP3 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV67821958; called by mutect2, varscan2
- SCUBE3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs776672878, COSV51456459; called by muse, mutect2, varscan2
- SIPA1L3 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55913978; called by muse, mutect2, varscan2
- SLC37A1 | c.1522-1G>T p.X508_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV61402360; called by muse, mutect2, varscan2
- SNRK | c.1972C>A p.L658I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV56067896; called by muse, mutect2, varscan2
- SP110 | c.1585C>A p.L529M | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.596); catalogued as COSV51250497; called by muse, mutect2, varscan2
- SPOCK2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368465155; called by muse, varscan2
- TDRD6 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60175636; called by muse, mutect2, varscan2
- TOX | c.694-1G>T p.X232_splice | Splice Site (SNP) | VAF 48/103 reads (47%) | catalogued as COSV63846079; called by mutect2, varscan2
- WSCD2 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54582733; called by muse, mutect2, varscan2
- EIF4G3 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by mutect2, varscan2
- EXPH5 | c.5899G>T p.D1967Y | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- LYVE1 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- WDR72 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- ALG6 | c.1065C>A p.V355= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54764967; called by mutect2, varscan2
- CCAR2 | c.1794C>A p.P598= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV52384491, COSV52384732; called by muse, mutect2, varscan2
- CEL | c.741G>T p.L247= (on ENST00000673714; = p.L244= on NM_001807.6) | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV60826228; called by mutect2, varscan2
- DDN | c.2100C>A p.I700= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV70404588; called by muse, mutect2, varscan2
- DHX35 | c.741C>A p.I247= | Silent (SNP) | VAF 102/220 reads (46%) | catalogued as rs201971902, COSV52667095, COSV52670146; called by mutect2, varscan2
- FBXL17 | c.1449C>A p.I483= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV62853375; called by muse, mutect2, varscan2
- GNAS | c.1173C>T p.Y391= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1254063262, CM107199, COSV55675973; ClinVar: likely benign; called by mutect2, varscan2
- GPC3 | c.843C>A p.V281= | Silent (SNP) | VAF 72/206 reads (35%) | catalogued as COSV63664031; called by muse, mutect2, varscan2
- HNRNPA0 | c.912C>A p.S304= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV59246549; called by mutect2, varscan2
- IQGAP2 | c.4140G>T p.T1380= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV57173175; called by muse, mutect2, varscan2
- LRCH1 | c.2073C>A p.A691= | Silent (SNP) | VAF 134/330 reads (41%) | catalogued as COSV60847209; called by muse, mutect2, varscan2
- NDST1 | c.498C>A p.I166= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV55787164; called by muse, mutect2, varscan2
- ONECUT1 | c.540G>T p.S180= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs140790810, COSV59949943; called by muse, mutect2, varscan2
- OR2D3 | c.498C>A p.A166= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV53492991; called by muse, mutect2, varscan2
- SLC11A2 | c.1557C>A p.I519= (on ENST00000394904 / NM_001379455.1; = p.I490= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV50370745; called by mutect2, varscan2
- SLC22A5 | c.627C>A p.S209= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV55372940, COSV55375345; called by muse, mutect2, varscan2
- TRPS1 | c.2676C>G p.S892= (on ENST00000220888 / NM_001330599.2; = p.S905= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV55237032, COSV55239631; called by muse, mutect2, varscan2
- TSSK6 | c.186C>A p.S62= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV53063628; called by muse, mutect2, varscan2
- DST | c.4296+4648G>T | Intron (SNP) | VAF 24/83 reads (29%) | catalogued as COSV54995909; called by muse, mutect2, varscan2
